Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A5BV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A5BV-01A (Primary Tumor).

[page 1 of 5]
ICD-O-3

Carcinoma, Urothelial NOS
8120/3

Gender: Female

Path Site: Bladder lateral Wall,
posterior Wall and Trigone

Race: White

C67.8

C&CF Site: Bladder, Trigone C67.0

Pathology Report:

JW, 12/24/12

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph node; dissection:

- Seventeen lymph nodes, no tumor (0/17).

B. Left pelvic lymph node; dissection:

- Eight lymph nodes, no tumor (0/8).

C. Urinary bladder; robotic-assisted laparoscopic cystectomy:

- Invasive high grade urothelial carcinoma invading thru the bladder wall and into the perivesical tissue, see pathologic parameters.

D. Uterus, cervix, bilateral fallopian tubes and ovaries; total abdominal hysterectomy and bilateral salpingo-oophorectomy:

- Uterus with atrophic endometrium, no tumor.
- Bilateral ovaries with age related changes, no tumor.
- Bilateral fallopian tubes, no tumor.
- Cervix, no tumor.

E. Vermiform appendix; appendectomy:

- Appendix, no tumor.

F. Left distal ureter; excision:

- Portion of ureter, no tumor.

G. Right distal ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (macroscopic).

[page 2 of 5]
4. Tumor distribution: Solitary, 6.0 cm, mass at left lateral wall, trigone and posterior wall with focal extensions to dome and right lateral wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/25).
9. pTNM: pT3b,N0,MX.

Effective _____, this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

[] MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD

Electronically Signed Out by [], MD

Clinical History:

Patient is a _____ year-old female with invasive high-grade urothelial carcinoma of the bladder undergoing robotic assisted laparoscopic cystectomy.

Specimens Received:

- A: Right pelvic lymph node
- B: Left pelvic lymph node
- C: Bladder
- D: Uterus, cervix, and fallopian tubes
- E: Appendix
- F: Left distal ureter
- G: Right distal ureter

Gross Description:

The specimens are received in seven containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Right pelvic lymph node". Received fresh and placed in formalin is a 5.5 x 4.5 x 1.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 17 apparent lymph nodes ranging from 0.5-1.5 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

- A1: 4 candidate lymph nodes
- A2: 4 candidate lymph nodes
- A3: 4 candidate lymph nodes
- A4: 5 candidate lymph nodes

[page 3 of 5]
B. The second container is additionally identified as, "2. Left pelvic lymph node". Received fresh and placed in formalin is a 4 x 4 by 2.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 9 apparent lymph nodes ranging from 0.4-1.8 cm in greatest dimension.

All apparent lymph nodes are submitted as follows:

B1: One candidate lymph node, bisected

B2: 4 candidate lymph nodes

B3: 4 candidate lymph nodes

C. The third container is additionally identified as, "3. Bladder ". Received fresh and place in formalin is a 214.8 g cystectomy and urethrectomy specimen with overall measurements of 13 x 9.5 x 4.5 cm. The bladder measures 7 x 6.5 x 4 cm. The right ureteral stump measures 2.4 cm in length by 0.5 cm in diameter, and the left measures 1.2 cm in length by 0.8 cm in diameter, and each demonstrates an intact patent lumen, although the left ureter demonstrates resistance to probing. The attached urethra measures 4.6 cm in length by 0.7 cm in diameter with a 7.5 x 2.5 cm portion of tan-pink skin anteriorly and tan-pink vaginal mucosa posteriorly. The serosal surface shows yellow lobulated fibroadipose tissue with focal cautery artifact. The bladder is inked blue on the right half and black on the left half. The specimen is opened anteriorly to reveal a 6 x 5.2 cm area of induration with partially ulcerated and heaped up, hemorrhagic mucosa involving the entire left lateral wall, posterior wall, and trigone and surrounding both right and left ureters. On cut section, the induration extends through the muscularis propria and into the perivesical adipose tissue, where it abuts the deep margin. The surrounding bladder mucosa is granular and pink-tan with a uniform 1 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent, although the left ureter demonstrates resistance to probing. The urethral mucosa is tan-pink and glistening, with no lesions. Photographs are taken.

Representative sections are submitted as follows:

C1: Left ureter resection margin

C2: Right ureter resection margin

C3: Distal urethral margin

C4-C6: Representative sections of urethra, full thickness to anterior vaginal wall

C7-C8: Induration, posterior wall, tandem sections, with closest approach to deep margin (C8)

C9: Induration, posterior wall

C10: Induration, left lateral wall

C11: Induration, trigone

C12: Uninvolved bladder mucosa bladder dome

C13: Uninvolved bladder mucosa anterior wall

C14: Uninvolved bladder mucosa right lateral wall

D. The fourth container is additionally identified as, "4. Uterus, cervix,

[page 4 of 5]
tubes". Received fresh and placed in formalin is a 42.9 gm hysterectomy specimen with attached bilateral adnexa. The uterus measures 3.2 cm from fundus to lower uterine segment by 3.2 cm from cornu to cornu by 2.3 cm from anterior to posterior. The serosal surface is red-tan and glistening. The cervical face is pink-tan, glistening and measures 2 x 1.9 cm with a 1 cm slitlike os. The anterior surface is inked black and the posterior surface is inked blue. The specimen is opened revealing a 2.7 cm endocervical canal lined with tan-pink mucosa a triangular endometrial cavity measuring 0.7 cm from cornu to cornu by 1.2 cm in length and lined with tan-pink, endometrium measuring 0.1 cm in thickness. The specimen is sectioned reveal pink-tan myometrium which is up to 0.7 cm in greatest thickness.

The left adnexa structure consists of an 8 cm long and 0.4 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned revealing a pinpoint lumen and a 0.2 cm wall thickness. The attached white-tan, cribriform ovary measures 2 x 1.6 x 0.8 cm and is sectioned to revealed fibrotic, white-tan, ovarian stroma.

The right adnexa structure consists of a 6 cm long and 0.5 cm diameter fimbriated fallopian tube. The serosa is pink-red and glistening. The specimen is serially sectioned revealing a pinpoint lumen and a 0.2 cm wall thickness. The attached white-tan, cribriform ovary measures 2.3 x 1.5 x 0.7 cm and is sectioned to revealed fibrotic, white-tan ovarian stroma.

Representative sections are submitted as follows:

D1: Anterior cervix

D2: Posterior cervix

D3: Anterior endomyometrium

D4: Posterior endomyometrium

D5-D6: Sections of left ovary and fallopian tube

D7: Section of right ovary and fallopian tube

E. The fifth container is additionally identified as, "5. Appendix". Received fresh and placed in formalin is a 7 cm in length by 0.6 cm in external diameter vermiform appendix. The resection margin is inked blue. The serosal surface is tan-pink and smooth. The specimen is serially sectioned to reveal a wall thickness of 0.1 cm. The lumen is patent with soft tan-brown material. Representative sections of the body, resection margin, and longitudinal appendiceal tip are submitted in E1.

F. The sixth container is additionally identified as, "6. Left distal ureter". Received fresh and placed in formalin is a tan, soft portion of ureter measuring 0.5 cm in length by 0.5 cm in diameter. The specimen is oriented with a stitch on the non-margin side. The margin is inked black and the specimen is bisected and entirely submitted as F1.

[page 5 of 5]
G. The seventh container is additionally identified as, "7. Right distal ureter". Received fresh and placed in formalin is a soft, tan portion of ureter measuring 2.5 cm in length by 0.6 cm in diameter. The specimen is oriented with a stitch on the non-margin side. The margin is inked black and the specimen is serially sectioned and entirely submitted as G1.

xx
[], MD

Reviewed on: 12/18/12		

Source: NCI Genomic Data Commons file f178f091-c854-4344-b0d1-923b4e5d703c (TCGA-FD-A5BV.9CD8EA72-6DF6-4DD6-9F32-610AB97C9E0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).